Somatic mutation profile of tumor specimen 0DWES9 from CCDI case PBCNZK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.7 years (3,545 days).
Specimen 0DWES9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 799e3091-8309-497a-bc80-5e06d6ccc6ee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWES0 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b5d1fee1-34ac-4c46-9d52-93fe1e0382d3

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNMT3A | c.1903C>T p.R635W | Missense Mutation (SNP) | VAF 73/248 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs144689354, CM137477, COSV53038925; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- FAM184B | c.1668A>G p.E556= | Silent (SNP) | VAF 20/497 reads (4%) | called by muse, mutect2
